Somatic mutation profile of tumor specimen MMRF_1525_1_BM_CD138pos (aliquot MMRF_1525_1_BM_CD138pos_T2_KBS5U_K11917) from MMRF case MMRF_1525, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,111 days).
Specimen MMRF_1525_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 322ed285-c371-4964-9d37-b463e44237a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1525_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1525_1_PB_Whole_C7_KBS5U_K11905; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afae7023-7ea0-4762-9717-e633300556e8

The open-access MAF lists 75 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 18, Silent 14, Intron 7, Splice Region 3, 5'UTR 3, Nonsense Mutation 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs758156173, COSV62322448; called by mutect2, varscan2
- ALKBH8 | c.1642A>G p.M548V | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs989864551; called by muse, mutect2, varscan2
- CARF | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 43/113 reads (38%) | catalogued as COSV57546840; called by muse, mutect2, varscan2
- CIC | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs766113983; called by muse, mutect2, varscan2
- CNTN3 | c.2703G>A p.T901= | Splice Region (SNP) | VAF 45/181 reads (25%) | catalogued as rs201061027, COSV55167965; called by muse, mutect2, varscan2
- DNAH8 | c.5937C>T p.I1979= | Splice Region (SNP) | VAF 20/78 reads (26%) | catalogued as COSV59479437; called by muse, mutect2, varscan2
- HPS3 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV56055885, COSV99937709; called by muse, varscan2
- IGHV2-70 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs373390524; called by muse, varscan2
- IGHV2-70 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371561110; called by muse, mutect2, varscan2
- MGST1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as rs763132041, COSV50566470; called by muse, mutect2, varscan2
- MICU3 | c.888+6T>A | Splice Region (SNP) | VAF 24/85 reads (28%) | catalogued as COSV58846452; called by muse, mutect2, varscan2
- RYR1 | c.7064G>A p.R2355Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs144526634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM15 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAMTSL3 | c.1930del p.T644Rfs*25 | Frame Shift Del (DEL) | VAF 54/209 reads (26%) | called by mutect2, pindel*, varscan2*
- ARSI | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BRD2 | c.1253T>G p.V418G | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C3orf62 | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CCDC186 | c.1964T>G p.L655R | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCHS1 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ERLIN1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.461); called by muse, mutect2
- FREM2 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GARNL3 | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IFFO1 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- IGHV1-69D | c.221T>C p.F74S | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, varscan2
- IGHV2-70D | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOTCH1 | c.412T>C p.C138R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOF | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN2A | c.167T>C p.L56S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC35F3 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOHLH1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- THUMPD2 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBTB39 | c.1057_1064del p.E353Hfs*51 | Frame Shift Del (DEL) | VAF 41/183 reads (22%) | called by mutect2, pindel, varscan2
- C3orf62 | c.168C>T p.F56= | Silent (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2, varscan2
- CHST3 | c.546G>A p.A182= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV64151977; called by muse, mutect2, varscan2
- FCRL1 | c.783C>T p.S261= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV63825872; called by muse, mutect2
- FRY | c.4105C>T p.L1369= | Silent (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- FRY | c.7509A>G p.Q2503= | Silent (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.216T>A p.P72= | Silent (SNP) | VAF 43/180 reads (24%) | called by muse, varscan2
- LAMA1 | c.3768T>A p.P1256= | Silent (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- MUC22 | c.1374A>T p.T458= | Silent (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- NOS1AP | c.787C>T p.L263= | Silent (SNP) | VAF 63/143 reads (44%) | catalogued as COSV100723507; called by muse, mutect2, varscan2
- PROSER3 | c.1308G>A p.A436= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- TNKS | c.1011C>T p.D337= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs764674010; called by muse, mutect2, varscan2
- TRIO | c.6927C>T p.G2309= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1234734191; called by muse, varscan2
- TTC16 | c.1080C>T p.D360= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs778597218; called by muse, mutect2, varscan2
- UBE2O | c.552C>A p.I184= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- ADGRD1 | c.*283G>A | 3'UTR (SNP) | VAF 8/105 reads (8%) | catalogued as rs1474749632; called by muse, mutect2
- AP3D1 | c.2799+68A>G | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- ASXL2 | c.*2927T>A | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- BORCS7 | c.-11C>G | 5'UTR (SNP) | VAF 48/185 reads (26%) | catalogued as rs530184624; called by muse, mutect2, varscan2
- BRWD3 | c.*3066A>C | 3'UTR (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- C4orf50 | c.-742C>T | 5'UTR (SNP) | VAF 14/229 reads (6%) | catalogued as rs935834649; called by muse, mutect2
- CCDC57 | c.2241+2136C>T | Intron (SNP) | VAF 10/218 reads (5%) | catalogued as rs1211800992; called by muse, mutect2
- CYTH1 | c.*1003G>C | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- HPCAL4 | c.*2104T>G | 3'UTR (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- KCNH5 | c.2020-4221G>T | Intron (SNP) | VAF 9/300 reads (3%) | catalogued as rs1284183681; called by muse, mutect2
- KIF13B | c.*1754T>C | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- KRBOX1 | c.*47G>T | 3'UTR (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- MDFIC | c.-38G>A | 5'UTR (SNP) | VAF 30/91 reads (33%) | catalogued as rs775613352; called by muse, mutect2, varscan2
- MOCS2 | c.*483T>G | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- MT2A | c.*104A>G | 3'UTR (SNP) | VAF 26/57 reads (46%) | catalogued as rs1460263126; called by muse, mutect2, varscan2
- NAV2 | chr11:20118647 T>G | 3'Flank (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- NEURL4 | c.*29G>C | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- NPR3 | c.769+4099_769+4102del | Intron (DEL) | VAF 22/82 reads (27%) | catalogued as rs1461582199; called by pindel, varscan2
- NSG1 | c.*1351T>G | 3'UTR (SNP) | VAF 24/78 reads (31%) | catalogued as rs967851758; called by muse, mutect2, varscan2
- OTUD3 | c.*15G>A | 3'UTR (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- PAQR3 | c.*125+1260C>A | Intron (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- PHLDA3 | c.*17T>G | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- QSOX2 | c.*319A>G | 3'UTR (SNP) | VAF 25/74 reads (34%) | catalogued as rs1014981582; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*1755T>A | 3'UTR (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- SZT2 | c.*2220T>G | 3'UTR (SNP) | VAF 98/252 reads (39%) | called by muse, mutect2, varscan2
- TRMT13 | c.*919T>A | 3'UTR (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- UGGT1 | c.195-831A>G | Intron (SNP) | VAF 51/129 reads (40%) | catalogued as rs1472019362; called by muse, mutect2, varscan2
- VWDE | c.*159C>G | 3'UTR (SNP) | VAF 7/92 reads (8%) | catalogued as rs1450861538; called by muse, mutect2
- ZBTB44 | c.1687-150T>C | Intron (SNP) | VAF 51/272 reads (19%) | called by muse, mutect2, varscan2
